Surgical pathology report (de-identified scan), TCGA case TCGA-DM-A28M, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University Of Michigan, specimen TCGA-DM-A28M-01A (Primary Tumor).

Path (First Tumor)

Tumor Site:	Descending Colon ☒			
Date of Cancer Sample Procurement:				
Histology:	Adenocarcinoma ☒			
Description of other histology:				
Grade:	Moderately Differentiated ☒			
Mucinous:	☐ No	☐ Yes	☒ Yes (Focal)	☐ Unknown
Signet Ring Feature:	☒ No	☐ Yes	☐ Yes (Focal)	☐ Unknown
Histologic Heterogeneity:	☐ No	☒ Yes	☐ Unknown	
Host Response:	None ☒			
Crohn's like reaction	☒ None	☐ Yes	☐ Unknown	
Plasma cell rich stroma	☐ No	☐ Yes	☐ Unknown	
Growth Pattern:	☒ Expansile	☐ Invasive	☐ Expansile and Invasive	☐ Unknown
Inflammatory Bowel Disease	☒ No	☐ Yes	☐ Unknown	
Angiolymphatic Invasion:	☒ No	☐ Yes	☐ Unknown	
Mutator Phenotype:	☐ No	☒ Yes	☐ Unknown	
Number of Slides	2			
Garland Necrosis present:	☐ No	☒ Yes	☐ Yes (Focal)	☐ Unknown
TIL Cells / HPF	3.4			
Pathologist Comment:				

1CD-0-3
adenocarcinoma, NOS 8140/3
Site: descending colon C18.6
for 5/3/11

ImPAA Discrepancy		//
Care is (circle):	QUALIFIED	UNQUALIFIED

Source: NCI Genomic Data Commons file 65ea40ad-aea8-4487-821d-dc8078aca086 (TCGA-DM-A28M.0A659279-BA92-44AF-9E93-80457ADEC729.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).